Gene-level copy-number profile of tumor specimen ALCH-B00X-TTP1-A from ALCHEMIST case ALCH-B00X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.0 years (22,639 days).
Specimen ALCH-B00X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cbd993b7-451b-4310-9970-97fdd2d7c735.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B00X-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/a6342fa9-0328-4588-8452-58cbcd197970

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 3,489; copy number 2: 55,011; copy number 3: 375; copy number 4: 12; copy number 5: 6; copy number 7: 3; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,918,350–15,950,981, 4 genes: MYCNOS, MYCNUT, MYCN, RN7SL104P.
- chr6:35,765,908–35,766,927, 1 gene: AL157823.1.
- chr8:10,525,532–10,554,166, 1 gene (within-gene range 0–2): PRSS55.
- chr11:48,880,111–48,902,181, 3 genes: AC027369.6, AC027369.3, AC027369.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:112,967–186,136, 5 genes, copy number 7–10 (within-gene range 2–10): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr20:63,707,465–63,744,050, 6 genes, copy number 5 (within-gene range 2–5): ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG.

Autosomal genes at a single copy (total copy number 1): 638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
